Gene-level copy-number profile of tumor specimen TARGET-40-PAVALD-01A from TARGET case TARGET-40-PAVALD, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.2 years (5,924 days).
Specimen TARGET-40-PAVALD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.afbfb6df-b41f-534d-8dba-32d18bb690b4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAVALD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 411 have no estimate.
https://portal.gdc.cancer.gov/files/3df0049e-04e1-47f4-ae82-0f3403aa98e3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 7,313; copy number 2: 15,775; copy number 3: 19,407; copy number 4: 11,067; copy number 5: 4,577; copy number 6: 1,127; copy number 7: 560; copy number 8: 295; copy number 9: 64; copy number 10: 10.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:199,269,500–199,471,266, 2 genes (within-gene range 0–1): SATB2, AC016746.1.
- chr2:234,050,679–234,356,038, 6 genes: SPP2, AC006037.2, AC006037.1, AC122134.1, RPS20P12, AC097713.2.
- chr3:116,921,328–116,932,238, 2 genes: AC069504.1, LINC00901.
- chr7:126,495,312–126,537,295, 3 genes: AC002057.2, AC000374.1, AC002057.1.
- chr13:48,328,084–48,444,704, 4 genes (within-gene range 0–1): PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 924 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,190,575–162,370,475, 98 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr1:168,375,524–179,358,680, 211 genes, copy number 8 (broad region; genes not listed).
- chr2:170,700,368–170,861,151, 10 genes, copy number 8 (within-gene range 5–8): AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4.
- chr2:172,084,740–173,052,893, 18 genes, copy number 7–9: DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2.
- chr2:180,473,137–181,680,665, 14 genes, copy number 7–10 (within-gene range 3–10): AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL.
- chr3:175,473,919–175,776,333, 6 genes, copy number 7–8: AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1.
- chr4:61,775,449–61,775,850, 1 gene, copy number 10: AC108161.1.
- chr4:68,509,441–68,670,652, 6 genes, copy number 7 (within-gene range 3–7): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:418,703–1,246,189, 30 genes, copy number 7: AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18.
- chr5:1,798,385–1,900,493, 8 genes, copy number 7: MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4.
- chr5:2,921,496–6,030,841, 35 genes, copy number 7–8 (within-gene range 6–8): AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC026736.1, AC010266.2, AC010266.1.
- chr5:41,306,952–45,895,970, 73 genes, copy number 7 (broad region; genes not listed).
- chr6:44,809,317–45,377,953, 1 gene, copy number 7 (within-gene range 4–7): SUPT3H.
- chr6:45,097,496–46,954,943, 26 genes, copy number 7: AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1.
- chr6:52,264,014–52,577,060, 4 genes, copy number 7 (within-gene range 4–7): MCM3, PAQR8, EFHC1, TRAM2.
- chr7:24,778,444–25,949,986, 21 genes, copy number 7–9: AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2, AC091705.1, AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A.
- chr8:63,769,428–63,813,937, 1 gene, copy number 7: LINC01289.
- chr8:73,215,929–76,867,281, 62 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:78,605,952–81,759,515, 74 genes, copy number 7 (broad region; genes not listed).
- chr8:82,514,568–82,677,153, 1 gene, copy number 7: AC060765.1.
- chr8:112,446,575–112,539,317, 2 genes, copy number 9: AC024996.1, RPL30P16.
- chr8:114,791,653–114,791,929, 1 gene, copy number 7: CARS1P2.
- chr8:115,950,511–116,944,487, 10 genes, copy number 7: LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD.
- chr8:117,017,946–117,018,248, 1 gene, copy number 7: RN7SL228P.
- chr8:120,761,253–122,733,804, 14 genes, copy number 7 (within-gene range 6–7): AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1.
- chr8:122,781,655–122,974,510, 1 gene, copy number 7 (within-gene range 6–7): ZHX2.
- chr8:122,977,026–126,292,788, 79 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:132,024,216–133,963,259, 35 genes, copy number 7–8 (within-gene range 6–8): OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2.
- chr8:134,211,865–134,320,447, 1 gene, copy number 7 (within-gene range 6–7): AC105180.1.
- chr8:135,457,456–139,508,971, 20 genes, copy number 7–8 (within-gene range 6–8): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1.
- chr14:25,647,304–26,143,305, 4 genes, copy number 7 (within-gene range 4–7): LINC02306, AL359396.1, AL359396.2, AL132633.1.
- chr15:71,332,120–71,352,460, 2 genes, copy number 7: AC064799.2, AC064799.1.
- chr15:97,572,185–100,342,005, 54 genes, copy number 7 (within-gene range 5–7): LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4, DNM1P46, AC090825.2, RN7SL484P, AC090825.1, AC084855.1, ADAMTS17, AC084855.2, RNA5SP402, AC022710.1.

Autosomal genes at a single copy (total copy number 1): 4,937. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
